Somatic mutation profile of tumor specimen MP2PRT-PAPEBX-TMP1-A (aliquot MP2PRT-PAPEBX-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPEBX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,738 days).
Specimen MP2PRT-PAPEBX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3de725a3-e711-4b82-bbb1-884e81d3c983.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPEBX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPEBX-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02c6fca3-37ef-4568-8ae8-c7e119de0169

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPO | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 37/535 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as rs370230012; called by muse, mutect2
- ITGB1BP2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 82/560 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs776137087; called by muse, mutect2, varscan2
- PLIN5 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 263/756 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs780779953; called by muse, mutect2, varscan2
- SETD2 | c.4567C>T p.R1523C | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57433049; called by muse, varscan2
- AMOT | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 220/695 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SETD2 | c.6110-27_6118delinsCAAACAAACCACCCTTTTCCCTTAGCAACTGAACA p.X2037_splice | Splice Site (DEL) | VAF 43/421 reads (10%) | called by mutect2*, pindel, varscan2*
- TGM7 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 45/696 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.08); called by muse, mutect2
- WIPF3 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 136/787 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
